HCMI case HCM-EXPT-1038-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/f9b191c8-60b1-49ee-bd4b-e45be987f59d

Demographics
Sex at birth: female; Year of birth: 1963.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 53.8 years (19,638 days); Prior treatment: Yes.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Neoadjuvant.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1038-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1038-C50-01A-01-S1-HE: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 0; Percent necrosis: 35; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1038-C50-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 15; Percent tumor nuclei: 15; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 75; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
